Gene-level copy-number profile of tumor specimen ALCH-AE8X-TTP1-A from ALCHEMIST case ALCH-AE8X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,067 days).
Specimen ALCH-AE8X-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3651e9fd-1c90-4856-aae6-f18f5e379a12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE8X-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/784b7b21-2ef2-427f-b6ac-4c474d00c7c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 350; copy number 2: 57,748; copy number 3: 177; copy number 4: 34; copy number 5: 56; copy number 6: 3; copy number 7: 12; copy number 9: 1; copy number 11: 5; copy number 15: 2; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,434,861–1,442,882, 1 gene: VWA1.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr10:120,434,983–120,440,376, 1 gene: AC073587.1.
- chr22:23,390,606–23,402,726, 2 genes: ZDHHC8P1, AP000344.2.
- chr22:41,981,304–41,982,217, 1 gene (within-gene range 0–2): Z99716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,175,748–149,259,987, 1 gene, copy number 5: AC245297.3.
- chr8:43,246,755–43,247,410, 2 genes, copy number 6: AC022616.5, AC022616.7.
- chr12:68,272,443–71,118,247, 65 genes, copy number 5–7 (broad region; genes not listed).
- chr15:28,378,621–28,405,033, 3 genes, copy number 6–15: GOLGA8F, RN7SL238P, ABCB10P3.
- chr15:28,454,660–28,457,783, 1 gene, copy number 5: AC091304.2.
- chr16:32,439,069–32,441,159, 1 gene, copy number 5: PABPC1P13.
- chr22:21,354,563–21,396,590, 7 genes, copy number 9–17: LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 345. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
